Somatic mutation profile of tumor specimen 0DUME5 from CCDI case PBCLFY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 17.1 years (6,235 days).
Specimen 0DUME5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0139c07a-3045-402e-a7c6-87d83bea9d49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DUMDO (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ec12668f-f317-4d53-94e7-a5588a7c66bd

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.1676T>C p.V559A | Missense Mutation (SNP) | VAF 270/847 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as rs121913517, CM013551, COSV55386973, COSV55388782, COSV55393324; ClinVar: likely pathogenic / pathogenic; called by muse, varscan2
- USP28 | c.2470C>T p.R824* | Nonsense Mutation (SNP) | VAF 236/680 reads (35%) | catalogued as rs905911526; called by muse, varscan2
- AKAP8L | c.1582A>T p.S528C | Missense Mutation (SNP) | VAF 79/289 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.847); called by muse, varscan2
- SMCO2 | c.652C>T p.L218= | Silent (SNP) | VAF 68/377 reads (18%) | called by muse, varscan2
